Somatic mutation profile of tumor specimen TCGA-AP-A0LH-01A (aliquot TCGA-AP-A0LH-01A-11W-A062-09) from TCGA case TCGA-AP-A0LH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.7 years (22,169 days).
Specimen TCGA-AP-A0LH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d8beba2-9e07-45f4-ba19-3264f0b366fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LH-10A (Blood Derived Normal), aliquot TCGA-AP-A0LH-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e034fbc-e76d-46e1-a5ab-a7699d140c24

The open-access MAF lists 48 somatic variants for this specimen: 40 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Frame Shift Ins 12, Silent 6, Frame Shift Del 2, Nonsense Mutation 2, 5'Flank 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 69/177 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.221); catalogued as CM126689, COSV55903618; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 76/90 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.1724A>G p.K575R | Missense Mutation (SNP) | VAF 91/432 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV61260128, COSV61272004; called by mutect2, varscan2
- BRWD3 | c.180G>C p.L60= | Splice Region (SNP) | VAF 12/62 reads (19%) | catalogued as COSV64751767; called by muse, mutect2
- BTN3A3 | c.1726C>G p.L576V | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.794); catalogued as COSV55072956; called by muse, mutect2, varscan2
- CDK17 | c.713A>T p.E238V | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54131915; called by mutect2, varscan2
- COLQ | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1008156537, COSV67525470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPEB4 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs1473566319, COSV54174549; called by mutect2, varscan2
- CTTNBP2 | c.4384C>A p.P1462T | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50437371; called by mutect2, varscan2
- DDX47 | c.696C>A p.Y232* | Nonsense Mutation (SNP) | VAF 12/380 reads (3%) | catalogued as rs1001312981, COSV61911847; called by muse, mutect2
- DUSP1 | c.1056T>A p.S352R | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV53320758; called by muse, mutect2, varscan2
- HTT | c.4823G>A p.R1608Q | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs899196481, COSV61866367; called by muse, mutect2, varscan2
- KIF5A | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 106/223 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs774586838, COSV54052942; called by muse, mutect2, varscan2
- L1CAM | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs1557092299, CM981152, COSV62829360; called by muse, mutect2, varscan2
- NEK11 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.289); catalogued as rs1317886436, COSV63582717; called by mutect2, varscan2
- NID2 | c.1134T>A p.D378E | Missense Mutation (SNP) | VAF 108/258 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs999020684, COSV53500287; called by muse, mutect2, varscan2
- PAK6 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV53046922; called by muse, mutect2, varscan2
- PAPPA2 | c.4384G>A p.V1462M | Missense Mutation (SNP) | VAF 332/491 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs765113647, COSV62805982, COSV99056651; called by mutect2, varscan2
- PCDH9 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs868294906, COSV60525236; called by muse, mutect2, varscan2
- PDCD11 | c.2432G>A p.S811N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV63934734; called by muse, mutect2, varscan2
- PLD2 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54008063; called by muse, mutect2, varscan2
- PLEKHO1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376545625; called by mutect2, varscan2
- PNISR | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV65080224; called by muse, mutect2, varscan2
- RELA | c.1643A>C p.Q548P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV58015575; called by muse, mutect2, varscan2
- TRMT13 | c.1415del p.N472Ifs*16 | Frame Shift Del (DEL) | VAF 59/171 reads (35%) | catalogued as COSV100734449; called by mutect2, pindel, varscan2
- ZNF536 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 667/702 reads (95%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs1249515909, COSV62830106; called by mutect2, varscan2
- AGPS | c.1821dup p.A608Cfs*2 | Frame Shift Ins (INS) | VAF 60/149 reads (40%) | called by mutect2, varscan2
- ARHGEF1 | c.2401dup p.D801Gfs*10 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- CDHR2 | c.2695dup p.L899Pfs*21 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- CHST6 | c.295_296insC p.V99Afs*10 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- FUT1 | c.21_22insG p.Q8Afs*84 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel
- GPR4 | c.691dup p.A231Gfs*167 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- LOXL2 | c.1761dup p.D588Rfs*52 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- PSME3 | c.415_416del p.W139Gfs*30 | Frame Shift Del (DEL) | VAF 129/423 reads (30%) | called by pindel, varscan2
- SLCO4A1 | c.1009+1dup | Frame Shift Ins (INS) | VAF 4/47 reads (9%) | called by mutect2, pindel
- SMYD5 | c.76dup p.R26Pfs*46 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- TMEM59L | c.562dup p.T188Nfs*28 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- XPO5 | c.1478dup p.C493Wfs*31 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- ZNF704 | c.416dup p.S140Vfs*13 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- BEGAIN | c.1560C>T p.D520= | Silent (SNP) | VAF 4/7 reads (57%) | catalogued as rs757465916, COSV62069611; called by muse, mutect2, varscan2
- MYBPC1 | c.2400G>T p.L800= (on ENST00000550270 / NM_206820.2; = p.L807= on NM_002465.4) | Silent (SNP) | VAF 51/145 reads (35%) | catalogued as COSV62255756; called by muse, mutect2, varscan2
- PCSK2 | c.822C>T p.N274= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs777570512, COSV52727967, COSV52739192; called by muse, mutect2, varscan2
- SLC43A3 | c.1188C>A p.I396= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV61450964; called by muse, mutect2, varscan2
- TRAF3IP2 | c.993C>T p.D331= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV60676697; called by muse, mutect2, varscan2
- XIRP2 | c.1719G>A p.S573= (on ENST00000628543; = p.S748= on NM_152381.6) | Silent (SNP) | VAF 123/284 reads (43%) | catalogued as rs769558004, COSV54720807, COSV99743893; called by mutect2, varscan2
- AP000769.5 | chr11:65500268 del TG | 5'Flank (DEL) | VAF 58/135 reads (43%) | called by pindel, varscan2
- GRIA4 | c.2544+81C>T | Intron (SNP) | VAF 90/205 reads (44%) | catalogued as rs1159354727, COSV56910434; called by muse, mutect2, varscan2
